TCGA case TCGA-BQ-7046 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08a50ae7-179c-4241-8aed-79db6c218c90

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.2 years (22,337 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC clinical T: T1a; AJCC clinical N: NX; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,948 days (8.1 years).
   Pathology details: Consistent pathology review: Yes.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 2,948 days (8.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Calcium: Low.
- Platelets: Normal.
- Leukocytes: Normal.
- Hemoglobin: Low.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85.7 kg; Height: 180 cm; BMI: 26.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BQ-7046-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.1; Shortest dimension: 0.4.
  Slide TCGA-BQ-7046-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 12; Percent neutrophil infiltration: 0.
- Sample TCGA-BQ-7046-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BQ-7046-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.5; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Serum calcium level: Low; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 3.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Face; Other malignancy histological type: Basal Cell Carcinoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy basal cell carcinoma of the face. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,948 days; disease-specific survival: no event (censored), 2,948 days; progression-free interval: no event (censored), 2,948 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BQ-7046-01A-11D-1959-01): tumor purity 0.66, ploidy 2.36, whole-genome doublings 0.
